Somatic mutation profile of tumor specimen TARGET-40-PAPFLB-01A (aliquot TARGET-40-PAPFLB-01A-01D) from TARGET case TARGET-40-PAPFLB, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 15.0 years (5,496 days).
Specimen TARGET-40-PAPFLB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f1bd4d4-df05-459b-b797-fc69ff7cefe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPFLB-10A (Blood Derived Normal), aliquot TARGET-40-PAPFLB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75981c03-7c94-489f-bff8-4f791befaa2c

The open-access MAF lists 27 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 5, 3'UTR 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB2 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 393/875 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs772533912, COSV63505955; called by muse, mutect2, varscan2
- LMAN1L | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV59001781; called by muse, mutect2, varscan2
- ORM2 | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 94/432 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs756377807; called by muse, mutect2, varscan2
- OVCH1 | c.63A>G p.L21= | Splice Region (SNP) | VAF 16/518 reads (3%) | catalogued as rs956309695; called by muse, mutect2
- P2RX6 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 195/528 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374202799; called by muse, mutect2, varscan2
- RELN | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633245; called by muse, mutect2, varscan2
- CD14 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 297/690 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.8098G>C p.V2700L | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CDHR5 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 153/353 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CLDN24 | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 84/690 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R37 | c.1036_1059del p.G346_L353del | In Frame Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- TFRC | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRBV20-1 | c.325A>C p.S109R | Missense Mutation (SNP) | VAF 258/1012 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- WNK1 | c.4959G>T p.K1653N (on ENST00000315939 / NM_018979.4; = p.K1406N on NM_014823.3) | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CLPS | c.183C>T p.S61= | Silent (SNP) | VAF 222/1159 reads (19%) | catalogued as rs144552522; called by muse, mutect2, varscan2
- FAT2 | c.267G>C p.V89= | Silent (SNP) | VAF 201/1043 reads (19%) | called by muse, mutect2, varscan2
- OR5D3P | c.66C>A p.I22= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs1373148935; called by muse, mutect2, varscan2
- PRAME | c.423C>G p.A141= | Silent (SNP) | VAF 42/305 reads (14%) | called by muse, mutect2, varscan2
- TEC | c.1230T>C p.F410= | Silent (SNP) | VAF 64/368 reads (17%) | called by muse, mutect2, varscan2
- TFRC | c.207G>A p.G69= | Silent (SNP) | VAF 41/278 reads (15%) | called by muse, mutect2, varscan2
- EMC4 | c.202-113C>A | Intron (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- HNRNPM | c.2029+46G>A | Intron (SNP) | VAF 203/562 reads (36%) | catalogued as rs1313233334; called by muse, mutect2, varscan2
- LINGO2 | c.-111-19011G>A | Intron (SNP) | VAF 448/994 reads (45%) | called by muse, varscan2
- SLC19A1 | c.*112A>C | 3'UTR (SNP) | VAF 61/158 reads (39%) | called by muse, mutect2, varscan2
- SPG11 | c.2620+125A>T | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- SPTA1 | c.6531-13C>T | Intron (SNP) | VAF 81/357 reads (23%) | called by muse, mutect2, varscan2
- TAF11 | c.*31C>T | 3'UTR (SNP) | VAF 50/283 reads (18%) | catalogued as rs771253931; called by muse, mutect2, varscan2
